Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAO6, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAO6-01A (Primary Tumor).

[page 1 of 2]
Name:

Operative Procedure: ORCHIECTOMY

- Specimen Source: L TESTIS AND CORD
- Gross Exam Date:
- Physician:

ICD-0-3
Seminoma NOS 9061/3
Site: O Testis NOS
CL 2.9
p 3/31/14
Pager No.:

PRELIMINARY DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA, left testes and cord, radical orchiectomy.
2. NO TUMOR IDENTIFIED IN VAS DEFERENS AND TUNICA ALBUGINEA.
3. NO DEFINITIVE LYMPHOVASCULAR INVASION IDENTIFIED.
4. NO INTRATUBULAR GERM CELL NEOPLASIA IDENTIFIED.
5. ATROPHIC TESTICULAR TISSUE WITH HYALINIZATION OF TUBULES.
6. pT1NXMX.

Note: Malignant cells present in the blood vessels are most likely due to carry over artifact. HCG and CAM 5.2 are negative.

GROSS DESCRIPTION:

The specimen is received unfixed labeled with the patient's name, and "left testes and cord". It consists of a 60 gram orchiectomy specimen including 5.5x4x4 cm testis, 1x1x0.3 cm epididymis and 5.5 cm in length and 1.3 cm in diameter spermatic cord. 0.5 cm from the base of the epididymis and 0.2 cm from tunica albuginea, there is a 3.5x3.2x2 cm white-tan, fleshy, variegated, well-circumscribed mass with focal area of hemorrhage and necrosis. There is no gross involvement of the tunica albuginea or impingement of the epididymis. The rim of testicular parenchyma at the age of the tumor is compressed and grossly unremarkable. The spermatic cord consists of vas deferens, arteries, veins and it is unremarkable.

SUMMARY OF CASSETTES:

- Cassette #1 - spermatic cord resection margin.
- Cassette #2 - spermatic cord mid-portion.
- Cassette #3 - spermatic cord paratesticular portion.
- Cassette #4 - tumor and base of the epididymis.
- Cassette #5 - tumor and tunica vaginalis.
- Cassette #6 - tumor and adjacent testis.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 2]
Name:

Operative Procedure: ORCHIECTOMY

- Specimen Source: L TESTIS AND CORD
- Gross Exam Date:
- Physician:

Pager No.:

Cassettes #7 to #11 - representative section of tumor.
Cassette #12 - tumor and epididymis.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

Source: NCI Genomic Data Commons file 6111073d-f749-488b-adc0-2a1b78b42b38 (TCGA-XE-AAO6.034402B8-BD0D-4D47-B523-6EC1045186A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).